Somatic mutation profile of tumor specimen TCGA-DH-5140-01A (aliquot TCGA-DH-5140-01A-01D-1468-08) from TCGA case TCGA-DH-5140, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G3; Age at diagnosis: 38.2 years (13,943 days).
Specimen TCGA-DH-5140-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2ec40735-e0ec-4fe4-827a-d6b0886fcf24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DH-5140-10A (Blood Derived Normal), aliquot TCGA-DH-5140-10A-01D-1468-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9d0fc5e9-661a-4f1d-9327-34caacda22df

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 8 silent.
By variant classification: Missense Mutation 17, Silent 8, Frame Shift Del 4, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NF1 | c.2533T>C p.C845R | Missense Mutation (SNP) | VAF 108/120 reads (90%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as rs1060500254, CM143342, COSV62196244, COSV62202472; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.994-2A>C p.X332_splice | Splice Site (SNP) | VAF 16/50 reads (32%) | hotspot (GDC flag); catalogued as CS159286, COSV52692098, COSV52692518, COSV53122371; called by muse, varscan2
- TP53 | c.709A>G p.M237V | Missense Mutation (SNP) | VAF 46/123 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs730882004, COSV52701833, COSV52875518, COSV53198341; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ACAN | c.2683C>T p.P895S | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV61368031; called by muse, mutect2, varscan2
- ACOXL | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 80/200 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs547761662, COSV61329751; called by muse, mutect2, varscan2
- ATN1 | c.1697C>T p.P566L | Missense Mutation (SNP) | VAF 18/236 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.144); catalogued as COSV63112786; called by muse, mutect2
- CCDC40 | c.1247G>A p.R416H | Missense Mutation (SNP) | VAF 121/133 reads (91%) | SIFT tolerated (0.55); PolyPhen benign (0.272); catalogued as rs199666629, COSV53903584; called by muse, mutect2, varscan2
- COP1 | c.692A>G p.D231G | Missense Mutation (SNP) | VAF 85/185 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV58174475; called by muse, mutect2, varscan2
- CPA1 | c.775G>A p.A259T | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.092); catalogued as rs369665148; called by muse, mutect2
- H4C7 | c.43G>A p.G15S | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.991); catalogued as COSV55099622, COSV55099671; called by muse, mutect2, varscan2
- HLA-DQA2 | c.371C>T p.T124M | Missense Mutation (SNP) | VAF 130/284 reads (46%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs144060347; called by muse, mutect2, varscan2
- MAML2 | c.2679G>C p.Q893H | Missense Mutation (SNP) | VAF 116/211 reads (55%) | SIFT tolerated (0.41); PolyPhen benign (0.027); catalogued as COSV101594150, COSV73264561; called by muse, mutect2, varscan2
- NDUFAF3 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.229); catalogued as rs776803585, COSV58247179; called by muse, mutect2, varscan2
- PELI3 | c.1049C>T p.A350V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.8); PolyPhen benign (0.003); catalogued as rs751096914, COSV57857601; called by muse, mutect2, varscan2
- RBM11 | c.610G>A p.A204T | Missense Mutation (SNP) | VAF 104/489 reads (21%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.057); catalogued as COSV68748317; called by muse, varscan2
- SLC7A9 | c.754C>A p.L252M | Missense Mutation (SNP) | VAF 20/98 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV50092389; called by muse, mutect2, varscan2
- TP53 | c.1002del p.R335Vfs*10 | Frame Shift Del (DEL) | VAF 15/57 reads (26%) | catalogued as COSV99439495; called by pindel, varscan2
- UBXN7 | c.775G>A p.G259S | Missense Mutation (SNP) | VAF 20/268 reads (7%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV56357357; called by muse, mutect2
- ZCRB1 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 98/239 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.117); catalogued as COSV56892098; called by muse, mutect2, varscan2
- SETD2 | c.6241_6278del p.L2081Kfs*4 | Frame Shift Del (DEL) | VAF 158/798 reads (20%) | called by mutect2, pindel
- TP63 | c.1904del p.G635Vfs*69 | Frame Shift Del (DEL) | VAF 96/269 reads (36%) | called by mutect2, pindel, varscan2
- UGGT1 | c.3908del p.I1303Nfs*47 | Frame Shift Del (DEL) | VAF 48/135 reads (36%) | called by mutect2, pindel, varscan2
- ABCC12 | c.493C>T p.L165= | Silent (SNP) | VAF 80/184 reads (43%) | catalogued as rs1347708672, COSV60917596; called by muse, mutect2, varscan2
- ADGRL2 | c.4287T>C p.N1429= (on ENST00000370717 / NM_001366005.1; = p.N1373= on NM_012302.4) | Silent (SNP) | VAF 49/119 reads (41%) | catalogued as COSV54685190; called by muse, mutect2, varscan2
- INTS4 | c.1251T>A p.V417= | Silent (SNP) | VAF 47/70 reads (67%) | catalogued as COSV71091626; called by muse, mutect2, varscan2
- PLIN4 | c.2835C>T p.G945= (on ENST00000301286; = p.G960= on NM_001367868.2) | Silent (SNP) | VAF 34/117 reads (29%) | catalogued as rs369051267; called by muse, mutect2, varscan2
- SLC25A40 | c.891C>T p.S297= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs1394222074, COSV56696419; called by muse, mutect2, varscan2
- SLC28A1 | c.411G>A p.R137= | Silent (SNP) | VAF 25/184 reads (14%) | catalogued as rs372865550; called by muse, mutect2, varscan2
- SLX4 | c.2949C>T p.Y983= | Silent (SNP) | VAF 129/247 reads (52%) | catalogued as rs758944750, COSV53567818; called by muse, mutect2, varscan2
- SPTBN5 | c.2728T>C p.L910= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs758959405, COSV58027066; called by muse, mutect2
